CPTAC case C3L-02129 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aba43d9a-4044-44ce-8e33-37ea62f64cb9

Demographics
Sex at birth: male; Race: white; Year of birth: 1961; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 55.9 years (20,422 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M1; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Residual disease: RX; Days to last known disease status: -11 days; Days to last follow up: -11 days; Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 1.6 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Involved.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -11, day -6.

Other clinical attributes
- Weight: 67 kg; Height: 178 cm; BMI: 21.15; FEV1/FVC before bronchodilator (%): 94; FEV1 before bronchodilator (% of reference): 68.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 75; Cigarettes per day: 60; Tobacco smoking onset year: 1982; Tobacco smoking quit year: 2007; Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Exposure duration years: 25.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02129-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 127 mg; Time between excision and freezing: 25 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02129-23: Section location: Right Upper Lobe; Percent tumor nuclei: 75; Percent necrosis: 3.
- Sample C3L-02129-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 160 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02129-21: Section location: Right Upper Lobe; Percent tumor nuclei: 65; Percent necrosis: 5.
- Sample C3L-02129-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 89 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02129-24: Section location: Right Upper Lobe; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3L-02129-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -11 days; Method of sample procurement: Blood Draw.
